Somatic mutation profile of tumor specimen 0DFYQP from CCDI case PBBSXH, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 16.6 years (6,045 days).
Specimen 0DFYQP: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9904fb54-6a38-4842-8863-0f0e08b4043c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DFYPG (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f2480b3e-d554-4c85-b451-fa3e83ae09d7

The open-access MAF lists 35 somatic variants for this specimen: 29 protein-altering or splice-affecting, 4 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, Silent 4, Frame Shift Ins 2, Nonsense Mutation 2, Intron 1, Splice Site 1, 5'UTR 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.866C>T p.A289V | Missense Mutation (SNP) | VAF 431/699 reads (62%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs149840192, COSV51765841, COSV51768139; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.1015G>T p.E339* | Nonsense Mutation (SNP) | VAF 261/303 reads (86%) | catalogued as rs17882252, CM984588, COSV52705645, COSV52980241, COSV53040770, COSV53664260; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ANKRD36B | c.328G>A p.A110T | Missense Mutation (SNP) | VAF 348/873 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV51536395; called by muse, mutect2, varscan2
- CASP10 | c.8C>A p.S3Y | Missense Mutation (SNP) | VAF 18/272 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.108); catalogued as COSV104376303; called by muse, mutect2
- EMC1 | c.400G>T p.V134F | Missense Mutation (SNP) | VAF 48/784 reads (6%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.876); catalogued as rs1171450971; called by muse, mutect2
- ENPEP | c.208C>T p.P70S | Missense Mutation (SNP) | VAF 45/898 reads (5%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs753414298; called by muse, mutect2
- GLRA1 | c.722G>A p.R241Q | Missense Mutation (SNP) | VAF 203/447 reads (45%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.962); catalogued as rs375819582, COSV51013548; ClinVar: benign; called by muse, mutect2, varscan2
- GOLGA6L6 | c.1101A>G p.I367M | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs200650686; called by muse, varscan2
- GPNMB | c.445G>A p.G149S | Missense Mutation (SNP) | VAF 46/838 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs776093177, COSV51697161; called by muse, mutect2
- LCOR | c.859G>A p.A287T | Missense Mutation (SNP) | VAF 11/358 reads (3%) | SIFT tolerated (0.56); PolyPhen benign (0.013); catalogued as rs1252580231, COSV63629918; called by muse, mutect2
- LRP1B | c.6481C>G p.R2161G | Missense Mutation (SNP) | VAF 135/644 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.182); catalogued as COSV67215667; called by muse, mutect2, varscan2
- MYO1B | c.2247G>T p.Q749H | Missense Mutation (SNP) | VAF 54/427 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV58432079; called by muse, varscan2
- PEX6 | c.149C>G p.P50R | Missense Mutation (SNP) | VAF 150/169 reads (89%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.557); catalogued as COSV55101666; called by muse, mutect2, varscan2
- RYR3 | c.4492G>A p.V1498M | Missense Mutation (SNP) | VAF 46/666 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.977); catalogued as rs375515948; called by muse, mutect2
- SH2D4B | c.682C>T p.R228* | Nonsense Mutation (SNP) | VAF 42/714 reads (6%) | catalogued as rs745382092, COSV57894420; called by muse, mutect2
- TRUB1 | c.1026A>T p.E342D | Missense Mutation (SNP) | VAF 112/134 reads (84%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.039); catalogued as rs1483071040; called by muse, mutect2, varscan2
- ARID1B | c.2728A>C p.M910L | Missense Mutation (SNP) | VAF 24/549 reads (4%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.001); called by muse, mutect2
- EZHIP | c.251C>T p.S84L | Missense Mutation (SNP) | VAF 344/387 reads (89%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- FRMD4A | c.2146G>A p.G716S | Missense Mutation (SNP) | VAF 22/489 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.012); called by muse, mutect2
- MN1 | c.1214C>T p.A405V | Missense Mutation (SNP) | VAF 35/444 reads (8%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.254); called by muse, mutect2
- MS4A18 | c.204C>A p.N68K | Missense Mutation (SNP) | VAF 174/390 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- PCSK6 | c.601G>T p.V201F | Missense Mutation (SNP) | VAF 47/576 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PPP6R3 | c.972_975dup p.K326Qfs*25 (on ENST00000393800 / NM_001352375.2; = p.N326Qfs*11 on NM_018312.5) | Frame Shift Ins (INS) | VAF 121/314 reads (39%) | called by mutect2, varscan2
- PTPRO | c.268G>A p.G90S | Missense Mutation (SNP) | VAF 28/655 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- RAB3GAP1 | c.1673C>T p.P558L | Missense Mutation (SNP) | VAF 244/523 reads (47%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2, varscan2
- RFX1 | c.1372_1380del p.T458_Y460del | In Frame Del (DEL) | VAF 150/202 reads (74%) | called by mutect2, varscan2
- SNCA | c.-25-1G>C | Splice Site (SNP) | VAF 133/330 reads (40%) | called by muse, mutect2, varscan2
- SP140 | c.1836_1837insT p.K613* | Frame Shift Ins (INS) | VAF 296/666 reads (44%) | called by mutect2, varscan2
- TRMT1 | c.376A>G p.K126E | Missense Mutation (SNP) | VAF 44/490 reads (9%) | SIFT tolerated (0.4); PolyPhen benign (0.011); called by muse, mutect2
- APOBEC3D | c.330G>T p.L110= | Silent (SNP) | VAF 38/536 reads (7%) | called by muse, mutect2
- CUX2 | c.4122C>T p.H1374= | Silent (SNP) | VAF 37/630 reads (6%) | called by muse, mutect2
- ITGA2B | c.2181C>T p.N727= | Silent (SNP) | VAF 150/362 reads (41%) | catalogued as rs780092113; called by muse, mutect2, varscan2
- TENM2 | c.2445C>T p.N815= (on ENST00000518659 / NM_001122679.2; = p.N583= on NM_001080428.3) | Silent (SNP) | VAF 58/485 reads (12%) | catalogued as rs775997514; called by muse, mutect2, varscan2
- MAP7D1 | c.2025+22C>T | Intron (SNP) | VAF 22/740 reads (3%) | catalogued as rs1254478587; called by muse, mutect2
- WFDC1 | c.-44C>G | 5'UTR (SNP) | VAF 18/228 reads (8%) | catalogued as rs780440065, COSV54745117; called by muse, mutect2
